Somatic mutation profile of tumor specimen TCGA-SC-A6LM-01A (aliquot TCGA-SC-A6LM-01A-11D-A34C-32) from TCGA case TCGA-SC-A6LM, project TCGA-MESO (Mesothelioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 64.1 years (23,400 days).
Specimen TCGA-SC-A6LM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 901adb98-e56d-447f-9df2-34c6b5e0a5f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SC-A6LM-10A (Blood Derived Normal), aliquot TCGA-SC-A6LM-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d742b948-c2c3-4885-b394-5743b9875e2e

The open-access MAF lists 35 somatic variants for this specimen: 26 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 8, Nonsense Mutation 3, Intron 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPHA5 | c.392A>T p.K131I | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56657172; called by muse, mutect2, varscan2
- FLG | c.7117G>T p.G2373* | Nonsense Mutation (SNP) | VAF 22/95 reads (23%) | catalogued as rs557758384; called by muse, mutect2, varscan2
- ITGBL1 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as rs1052153988; called by muse, mutect2
- MASP1 | c.354C>G p.F118L | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV51461226; called by muse, mutect2, varscan2
- PCDHB10 | c.2254C>T p.Q752* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as rs1554284517; called by muse, mutect2, varscan2
- PKHD1 | c.193G>A p.V65M | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs749853418, COSV61890674; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPARGC1B | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763781481, COSV58530499; called by muse, mutect2, varscan2
- RNF214 | c.1400T>C p.I467T | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.948); catalogued as rs369438119; called by muse, mutect2, varscan2
- RYR3 | c.5996C>T p.A1999V | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs370551971; called by muse, mutect2, varscan2
- SLC12A5 | c.508G>A p.A170T (on ENST00000454036 / NM_001134771.2; = p.A147T on NM_020708.5) | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.461); catalogued as rs1025149041, COSV54798730, COSV54803212; called by muse, mutect2, varscan2
- TET1 | c.6112C>T p.R2038C | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65386977; called by muse, mutect2, varscan2
- TRPC4 | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 60/197 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59004943; called by muse, mutect2, varscan2
- TSKS | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as rs762103107; called by muse, mutect2, varscan2
- AGBL2 | c.1388C>A p.P463H | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPN1 | c.614A>T p.D205V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HLA-B | c.454_459del p.E152_D153del | In Frame Del (DEL) | VAF 10/44 reads (23%) | called by mutect2, pindel, varscan2
- IPO7 | c.1518T>G p.I506M | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- KIF21A | c.2215C>T p.Q739* (on ENST00000361418 / NM_001378440.1; = p.Q726* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | called by muse, varscan2
- LRP11 | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MED6 | c.623A>T p.K208M | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- MROH2B | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.265); called by muse, mutect2
- MYO5A | c.3844C>A p.P1282T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PHLDB2 | c.1784T>C p.I595T | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SLC39A13 | c.302-18_309del p.X101_splice | Splice Site (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel
- SMCR8 | c.2498A>G p.H833R | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- SPPL2A | c.463A>T p.N155Y | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- C1orf109 | c.162C>T p.N54= | Silent (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- CHRNA9 | c.264C>T p.H88= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as rs755484152, COSV59574322; called by muse, mutect2, varscan2
- KIF21A | c.2214T>C p.A738= (on ENST00000361418 / NM_001378440.1; = p.A725= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/43 reads (35%) | called by muse, varscan2
- SEMA5B | c.2496C>T p.C832= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as rs779747885; called by muse, mutect2, varscan2
- SLC6A11 | c.972C>T p.N324= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as rs1369832750; called by muse, mutect2, varscan2
- SRGAP1 | c.6C>T p.S2= | Silent (SNP) | VAF 29/91 reads (32%) | called by muse, mutect2, varscan2
- TFPT | c.291G>A p.E97= | Silent (SNP) | VAF 24/66 reads (36%) | called by muse, mutect2, varscan2
- ZNF282 | c.699C>T p.T233= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs765398196; called by muse, mutect2, varscan2
- METTL6 | c.531+243G>A | Intron (SNP) | VAF 29/87 reads (33%) | called by muse, mutect2, varscan2
